Somatic mutation profile of tumor specimen TCGA-OR-A5JZ-01A (aliquot TCGA-OR-A5JZ-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JZ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-OR-A5JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 083f5df5-df07-47d6-a11e-3a6c364bc2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JZ-10A (Blood Derived Normal), aliquot TCGA-OR-A5JZ-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92fd717b-6385-4166-afd0-418aaef10182

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV62426059; called by muse, mutect2, varscan2
- CNTNAP5 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs890816163, COSV70496411, COSV70507161; called by muse, mutect2, varscan2
- COL22A1 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.48); catalogued as rs144653941; called by muse, mutect2, varscan2
- SNRPB2 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs757434273; called by muse, mutect2, varscan2
- HAS3 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECW1 | c.1155_1172del p.E386_W391del | In Frame Del (DEL) | VAF 114/132 reads (86%) | called by mutect2, pindel, varscan2
- OPTN | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 86/98 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2T10 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SAGE1 | c.2265G>A p.M755I | Missense Mutation (SNP) | VAF 164/182 reads (90%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SAP18 | c.163G>A p.E55K (on ENST00000607003; = p.E74K on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/93 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC5A5 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STXBP5 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 118/198 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- DLC1 | c.2074T>C p.L692= (on ENST00000276297 / NM_001348081.2; = p.L255= on NM_006094.5) | Silent (SNP) | VAF 73/167 reads (44%) | catalogued as rs768363611; called by muse, mutect2, varscan2
- FBXO42 | c.1911G>A p.Q637= | Silent (SNP) | VAF 85/152 reads (56%) | called by muse, mutect2, varscan2
- FRAS1 | c.4848T>C p.L1616= | Silent (SNP) | VAF 55/66 reads (83%) | called by muse, mutect2, varscan2
